National Lung Screening Trial (NLST) participant 107206 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 67 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 128): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 210 mA, display field of view 34 cm, reconstruction filter Siemens, other.
- T1 (day 474): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: limited CT, but interpretable (lungs not completely imaged, other reason); technique as recorded on the form: 120 kVp, 150 mA, 40 effective mAs, display field of view 32 cm, reconstruction filter Siemens B30 / Siemens B50F.
- T2 (day 807): Negative screen, minor abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: limited CT, but interpretable (respiratory misregistration); technique as recorded on the form: 120 kVp, 150 mA, 40 effective mAs, display field of view 33 cm, reconstruction filter Siemens B30 / Siemens B50F.

Abnormalities recorded by the reading radiologist on the CT screens (16 abnormalities and 4 comparison-read records listed separately because the form numbering for that year does not link them to an abnormality of the same type; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 59.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 91.
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 94.
- T0 abnormality 4: Other potentially significant abnormality below the diaphragm.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 8 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 65.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 5 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 96.
- T1 abnormality 3: Other minor abnormality noted.
- T1 abnormality 4: Other potentially significant abnormality below the diaphragm.
- T1 abnormality 5: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 6: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 91.
- T1 comparison-read record 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); pre-existing on earlier images (earliest visible day 128); interval growth could not be determined; change in attenuation could not be determined.
- T1 comparison-read record 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); pre-existing on earlier images (earliest visible day 128); no interval growth; no suspicious change in attenuation.
- T1 comparison-read record 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); pre-existing on earlier images (earliest visible day 128); no interval growth; no suspicious change in attenuation.
- T1 comparison-read record 5: Other potentially significant abnormality below the diaphragm; pre-existing on earlier images (earliest visible day 128); whether interval change warrants investigation could not be determined.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 62; pre-existing on earlier images (earliest visible day 128); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 6 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 62; pre-existing on earlier images (earliest visible day 128); no interval growth; no suspicious change in attenuation.
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 94; pre-existing on earlier images (earliest visible day 128); no interval growth; no suspicious change in attenuation.
- T2 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 5 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 97; pre-existing on earlier images (earliest visible day 128); no interval growth; no suspicious change in attenuation.
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Other potentially significant abnormality below the diaphragm; pre-existing on earlier images (earliest visible day 128); whether interval change warrants investigation could not be determined.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,588.
